Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A4MW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A4MW-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code:

ICD-0-3

Patient Age/Sex / M

Oligoastrocytoma, anaplastic 9382/3
Site: brain, frontal lobe C71.1

SPECIMEN SUBMITTED:

Part A: RIGHT FRONTAL LOBE TUMOR

Part B: RIGHT FRONTAL BRAIN MASS

fw
10/4/12

Final Diagnosis

Right frontal lobe, excisional biopsy (A, B) - Anaplastic oligoastrocytoma (WHO grade III).
- See comment.

Diagnosis Comment:

The neoplasm is characterized by areas of predominant astrocytoma phenotype and areas with a mix cells with astrocytoma and oligodendroglioma phenotypes. Many of the areas have a low-grade histology, but foci present on permanent sections show a more anaplastic histology. In both areas, mitotic activity is readily identifiable. Ki-67 labeling index is 20%. No vascular proliferation or necrosis is seen. Between 10 and 25% of the nuclei label with antibodies to p53. The neoplastic cells do not label with antibodies to IDH1 (R132H).

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Excisional biopsy.

Specimen handling: Frozen section and permanent section.

Site: Frontal lobe

Laterality: Right

Diagnosis: Anaplastic oligoastrocytoma.

WHO Grade: III

Ancillary test(s) ordered: Immunohistochemistry for Ki-67, p53, IDH1(R132H), FISH for 1p, 19q, EGFR, all performed on block A2. IDH1(R132H) was also performed on block B1.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by Pathology and Laboratory Medicine. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Procedure: FISH for 1p/19q

Status: Signed Out

Text: ***** 1p/19q FISH RESULTS *****

RESULTS

Chromosome 1p: Intact, eusomic

Chromosome 19q: Intact, aneusomic

Quantitative FISH results:

1p36: 2.6

1q25: 2.5

1p36/1q25 ratio: 1.0

19q13: 3.5

19p13: 3.8

19q13/19p13 ratio: 0.9

SPECIMEN SUBMITTED: Paraffin block A2

INTERPRETATION

1p intact: A majority of nuclei showed similar numbers of 1p36 and 1q25 signals. There is no evidence of allelic loss on the short arm of chromosome 1 (1p).

19q intact: A majority of nuclei showed similar numbers of 19q13 and 19p13 signals. There is no evidence of allelic loss of 19q.

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the other allele.

Comment: Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss, aneusomy for chromosome 1 and 19 may be associated with earlier recurrence. References: Cairncross et al J Natl Cancer Inst 90:1473-1479, 1998; Smith et al, J Clin Oncol 18:636-645, 2000; Ino et al, J Neurosurg 92:983-990, 2000; Schmidt et al, J Neuropathol Exp Neurol 61:321-328, 2002; Snuderl et al, ClinCancer Res 15:6430-7, 2009.

Method: The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13) (

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

). The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by Pathology and Laboratory Medicine. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block A2

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-q11.1) (CEP7) locus specific directly labeled probes (

The following FISH results were obtained:

EGFR greater than 20 signals in the majority of tumor cells counted
CEP7 2.8

EGFR/CEP7 ratio greater than 7.1

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas (Smith JS, et al., J Natl Canc Inst 93:1246-1256, 2001; Ino et al., J Neurosurgery 92:983-990 2000).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by Pathology and Laboratory Medicine. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma

Clinical Diagnosis:

RIGHT FRONTAL BRAIN MASS

Gross Description:

A. Received fresh for intraoperative diagnosis labeled "right frontal brain mass" are three segments of tan-pink soft tissue measuring in aggregate 1.2 x 1 x 0.5 cm. One section is submitted for intraoperative diagnosis in FSA1. The remaining tissue is submitted entirely in A2.

B. Received fresh labeled "right frontal brain mass" are tan-pink, soft-gelatinous, irregular fragments aggregating to 2.7 x 2.5 x 0.5 cm. The specimen is totally submitted in cassettes B1-B2.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file c30cec6a-be5d-4694-8f7e-046f63f9c415 (TCGA-FG-A4MW.E9D4D450-3905-4D11-A814-7B1049A8F3A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).